Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB37, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB37-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

IED-C-3
Liposarcoma, dedifferentiated
8858/3
Site Thigh NOS
C49.2
9/3/10/14

Clinical Diagnosis & History:

with right thigh well differentiated dedifferentiated liposarcoma.

Specimens Submitted:

1: SP: Radical resection rt. thigh mass

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT THIGH; EXCISION:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA, 17.0 CM.
- THE HIGH GRADE COMPONENT COMPRISES APPROXIMATELY 30% OF THE SPECIMEN AND GROWS PREDOMINANTLY WITH A FIBROSARCOMA/MALIGNANT FIBROUS HISTIOCYTOMA-LIKE PATTERN.
- A LOW GRADE WELL-DIFFERENTIATED LIPOSARCOMA (LIPOMA-LIKE AND SCLEROSING PATTERNS) COMPONENT IS ALSO PRESENT, COMPRISING APPROXIMATELY 70% OF THE SPECIMEN.
- TUMOR INVADES SKELETAL MUSCLE.
- SURGICAL MARGINS ARE FREE OF TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, labeled "Radical Resection Right Thigh Mass". It consists of a 2,610 gram, 29.0 x 18.0 x 8.0 cm specimen consisting of a 32.0 x 5.5 cm strip of skin with a central, 10.0 cm, well-healed scar, underlying adipose tissue and skeletal muscle. The specimen is received oriented to the superior and lateral aspects of the specimen, and is oriented with the operating surgeon. Cut surfaces reveal a 17.0 x 6.0 x 5.0 cm, ill-defined, multinodular mass infiltrating the

PATH
REPORT

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
subcutaneous tissue and skeletal muscle. Cut surfaces of the mass reveal approximately 70% of the specimen consists of soft, yellow nodules of adipose tissue with focal areas of hemorrhage and necrosis, approximately 2 to 3%. In addition, approximately 30% of the specimen consists of uniform, gray, firm nodules. Both of these different areas infiltrate among skeletal muscle. The surgical margins are all grossly free of tumor. The tumor approaches most closely to the inferior deep soft tissue margin, approximately 0.5 cm. Sampled.

Summary of Sections:

S superior
I inferior
M medial
L lateral
D deep
SO softer areas
F firmer areas

Summary of Sections:

Part 1: SP: Radical resection rt. thigh mass

Block	Sect.	Site	PCs
1		D	1
6		F	6
1		I	1
1		L	1
1		M	1
1		S	1
7		SO	7

PATH
REPORT

** End of Report **

Criteria	lw 1/22/14	Yes	No

Source: NCI Genomic Data Commons file afb540df-15ae-4ed7-b73a-f4c7e2e6016a (TCGA-DX-AB37.8F7DB8E4-191C-4FB3-BEB3-B7AC0137EBC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).